Gene-level copy-number profile of tumor specimen TCGA-JW-A5VL-01A from TCGA case TCGA-JW-A5VL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G1; Age at diagnosis: 37.2 years (13,604 days).
Specimen TCGA-JW-A5VL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.05cec78c-1a12-4e5f-beb8-bf55d9c263d2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JW-A5VL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/83e98213-892e-433e-b3fb-1fa49c13de85

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,148; copy number 3: 5; copy number 4: 48,558; copy number 5: 1; copy number 6: 5,163; copy number 8: 1,153; copy number 9: 1,772; copy number 12: 10; copy number 14: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JW-A5VL-01A-11D-A28A-01): tumor purity 0.86, ploidy 2.2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,790 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:145,523,538–198,222,513, 933 genes, copy number 9 (broad region; genes not listed).
- chr8:93,698,561–145,066,685, 839 genes, copy number 9 (broad region; genes not listed).
- chr9:5,334,930–5,629,748, 8 genes, copy number 14 (within-gene range 6–14): RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2.
- chr17:68,793,549–69,244,846, 10 genes, copy number 12 (within-gene range 2–12): AC011591.1, ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
